MMRF case MMRF_1494 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ab7861e4-5034-417c-8d28-98b7c68252b3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.5 years (23,552 days); ISS stage: I; Days to last known disease status: 1,324 days (3.6 years); Days to last follow up: 1,324 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 34 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 35 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 65 days; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 90 days; Days to treatment end: 90 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 264 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 266 days; Days to treatment end: 266 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 268 days; Days to treatment end: 268 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 1.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 60.2 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 20.1 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.73 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 3.8 mmol/L.
- Day 91 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 9.65 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 177 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.992 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 199 ×10⁹/L.
- Day 281 (ECOG 2): Lactate Dehydrogenase 8.02 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 46 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.88 mmol/L; Albumin 22 g/L; Total Protein 4.1 g/dL; Glucose 4.62 mmol/L.
- Day 362 (ECOG 1): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.912 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.884 mg/dL; Immunoglobulin G 7.69 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 453 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.924 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.767 mg/dL; Immunoglobulin G 9.3 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.79 mmol/L.
- Day 544 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.29 mmol/L.
- Day 639 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.866 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.925 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 730 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 772 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.883 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 870 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 4.35 mmol/L.
- Day 961 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.894 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 1,052 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.848 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 1,143 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.95 mmol/L.
- Day 1,234 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.85 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 3.63 mmol/L.
- Day 1,324 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.85 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -13: Weight: 68 kg; Height: 149 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (1 sample)
- Sample MMRF_1494_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
